TCGA case TCGA-61-2104 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05263959-c4f5-4540-b6d2-d8c8a128861f

Demographics
Sex at birth: female; Race: white; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,432 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 2,338 days (6.4 years).
   Pathology details: Residual tumor measurement: No macroscopic disease; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 1,197 days (3.3 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,680 days (4.6 years); Days to treatment end: 1,681 days (4.6 years); Number of cycles: 1; Treatment dose: 200 mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Taxane Compound; Initial disease status: Recurrent Disease; Days to treatment start: 1,838 days (5.0 years); Days to treatment end: 2,338 days (6.4 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.8 years (21,112 days); Days to diagnosis: 1,680 days (4.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,680 days (4.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,680 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,680 days (4.6 years); Evidence of recurrence type: Convincing Image Source.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 2,338.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-61-2104-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 77; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-61-2104-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 12; Percent necrosis: 8; Percent stromal cells: 10.
- Sample TCGA-61-2104-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IP.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxane.
- Follow-up form: Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,338 days; disease-specific survival: no event (censored), 2,338 days; disease-free interval: event (new tumor event after initially disease-free), 1,680 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,680 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2104-01A-01D-0663-01): tumor purity 0.75, ploidy 3.05, whole-genome doublings 1.
